Somatic mutation profile of tumor specimen TCGA-EL-A3T7-01A (aliquot TCGA-EL-A3T7-01A-11D-A22D-08) from TCGA case TCGA-EL-A3T7, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 47.4 years (17,302 days).
Specimen TCGA-EL-A3T7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25037d47-7c1f-4a8f-927d-2387d05ef7e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3T7-11A (Solid Tissue Normal), aliquot TCGA-EL-A3T7-11A-21D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f93413d2-870e-4a54-9392-efb4958cda50

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ARHGEF10L | c.3058G>T p.V1020L | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV51436083; called by muse, mutect2, varscan2
- BAG2 | c.33C>G p.N11K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV62598465; called by muse, mutect2, varscan2
- CHAF1A | c.2249G>A p.S750N | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV56674284; called by muse, mutect2
- PROM2 | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV58299428; called by muse, mutect2
- RNF146 | c.277G>C p.E93Q (on ENST00000368314 / NM_001242850.2; = p.E92Q on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.743); catalogued as COSV100541665, COSV100541834; called by muse, mutect2, varscan2
- RNF146 | c.278A>T p.E93V (on ENST00000368314 / NM_001242850.2; = p.E92V on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100541666; called by muse, mutect2, varscan2
- SUPT6H | c.3649G>C p.D1217H | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV58929219; called by muse, mutect2, varscan2
- SYTL4 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 22/274 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs770652822, COSV52169468; called by muse, mutect2
- TPPP3 | c.141A>T p.G47= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV52084338; called by muse, mutect2, varscan2
